Somatic mutation profile of tumor specimen TCGA-BR-8367-01A (aliquot TCGA-BR-8367-01A-11D-2340-08) from TCGA case TCGA-BR-8367, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 56.0 years (20,441 days).
Specimen TCGA-BR-8367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 29bc559d-f3cf-49d7-b7e8-f051b3b3c134.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8367-10A (Blood Derived Normal), aliquot TCGA-BR-8367-10A-01D-2341-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3530da0-8b39-4718-8ed2-92e93c8f2c6e

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 14, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A3 | c.1216C>T p.R406* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as rs371334239, CM014040, COSV67417567; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM7 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs746112199, COSV51537523, COSV51541741; called by muse, mutect2
- ADCY3 | c.1579G>A p.A527T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as COSV99567505; called by muse, mutect2, varscan2
- ADGRB3 | c.3140T>G p.L1047R | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53253255, COSV53258799; called by muse, mutect2, varscan2
- ATP8B3 | c.3196G>A p.V1066M | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1388350716, COSV59545712; called by muse, mutect2
- BNC1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61756378; called by muse, mutect2
- BNC1 | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV61757819, COSV61758357; called by muse, mutect2, varscan2
- BRINP1 | c.1985T>A p.L662Q | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV56306696; called by muse, mutect2, varscan2
- C11orf58 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as COSV57178882; called by muse, mutect2
- CD163 | c.1629A>C p.E543D | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV63135206; called by muse, mutect2, varscan2
- CNTN3 | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs199555851; called by muse, mutect2
- E2F2 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.725); catalogued as COSV62276604; called by muse, mutect2
- EIF5A | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV59751856; called by muse, mutect2, varscan2
- FNDC1 | c.835T>C p.S279P | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.39); catalogued as COSV51943339; called by muse, mutect2, varscan2
- GLP2R | c.806A>G p.Y269C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52327276; called by muse, mutect2, varscan2
- GPS2 | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 7/129 reads (5%) | catalogued as COSV100222599; called by muse, mutect2
- HMCN1 | c.3080A>C p.K1027T | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.505); catalogued as COSV54889062, COSV99623133, COSV99637782; called by muse, mutect2, varscan2
- INA | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.251); catalogued as COSV63976292; called by muse, mutect2, varscan2
- INSRR | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.92); catalogued as rs752601283, COSV63872533; called by muse, mutect2, varscan2
- IRX4 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1280567257, COSV51473907; called by muse, mutect2, varscan2
- ITGAD | c.1757C>T p.A586V | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as rs144853512; called by muse, mutect2
- KLF5 | c.1253A>G p.D418G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV66614131, COSV66614346; called by muse, mutect2, varscan2
- KLHL5 | c.1126A>T p.N376Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54676911; called by muse, mutect2, varscan2
- KRT17 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV60861391; called by muse, mutect2, varscan2
- MYO1F | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs770373423, COSV100596860, COSV57797813; called by muse, mutect2, varscan2
- PCDHA3 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.052); catalogued as COSV63543986; called by muse, varscan2
- PDZD2 | c.2489G>A p.S830N | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as COSV56865438; called by muse, mutect2, varscan2
- POGZ | c.2966C>T p.T989I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as rs1416701735, COSV51852455; called by muse, mutect2, varscan2
- PRRC2A | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as rs777738037, COSV65687011; called by muse, mutect2, varscan2
- PSAPL1 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.595); catalogued as rs377051073; called by muse, mutect2, varscan2
- SATB1 | c.2131G>A p.G711S | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs776281718, COSV58671373; called by muse, mutect2, varscan2
- SCN10A | c.484G>T p.V162F | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); catalogued as COSV71862244; called by muse, mutect2, varscan2
- SFMBT2 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62813254; called by mutect2, varscan2
- SLC12A1 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs772165520, COSV57710771; called by muse, mutect2, varscan2
- SLC6A17 | c.2174C>T p.S725L | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs539335942, COSV58993479; called by muse, mutect2, varscan2
- SLX4 | c.4483G>A p.A1495T | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.516); catalogued as rs762565535, COSV53565420; called by muse, mutect2
- SOHLH2 | c.697G>C p.G233R | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV65903033; called by muse, mutect2
- STS | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM160345, COSV99480836; called by muse, mutect2
- STXBP1 | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs1388279646, COSV64814275; called by muse, mutect2, varscan2
- TMEM52B | c.227G>T p.G76V (on ENST00000381923 / NM_001079815.1; = p.G56V on NM_153022.4) | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.718); catalogued as COSV53728988; called by muse, mutect2, varscan2
- TRIM58 | c.1234G>T p.G412W | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63571443; called by muse, mutect2
- WRN | c.2597T>G p.V866G | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV53303850; called by muse, mutect2, varscan2
- ZNF426 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53470017; called by muse, mutect2, varscan2
- ACVR2A | c.298_309del p.V100_C103del | In Frame Del (DEL) | VAF 23/101 reads (23%) | called by pindel, varscan2
- AMY2A | c.674T>G p.I225S | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RAD50 | c.418del p.M140* | Frame Shift Del (DEL) | VAF 21/80 reads (26%) | called by mutect2, pindel, varscan2
- SOX9 | c.767_768dup p.R257Gfs*23 | Frame Shift Ins (INS) | VAF 19/122 reads (16%) | called by mutect2, pindel, varscan2
- ZFP36L2 | c.478dup p.R160Pfs*314 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | called by mutect2, pindel, varscan2
- CACNA1E | c.3885G>C p.V1295= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100704965, COSV62406811; called by muse, mutect2, varscan2
- CDH11 | c.111G>A p.G37= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1405814198, COSV51769674; called by muse, mutect2
- CDH12 | c.465T>C p.D155= | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as COSV66391905, COSV66394402; called by muse, mutect2, varscan2
- CNTNAP5 | c.852G>A p.T284= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs370887782; called by muse, mutect2, varscan2
- EGF | c.2883G>A p.R961= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV54481613; called by muse, mutect2, varscan2
- GRIK1 | c.378C>T p.L126= | Silent (SNP) | VAF 28/154 reads (18%) | catalogued as rs778306255, COSV58720480, COSV58725400; called by muse, mutect2, varscan2
- MRPS15 | c.717G>C p.R239= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV100910681, COSV64152527; called by muse, mutect2, varscan2
- MTMR14 | c.1952G>A p.*651= (on ENST00000296003 / NM_001077525.3; = p.*539= on NM_022485.5) | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as rs1294082200, COSV56006412; called by muse, mutect2, varscan2
- MTMR4 | c.2763G>A p.E921= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs765065318, COSV60201820; called by mutect2, varscan2
- PCDHA4 | c.441G>A p.P147= | Silent (SNP) | VAF 42/138 reads (30%) | catalogued as COSV63540318; called by muse, mutect2, varscan2
- PCDHGA6 | c.180G>A p.A60= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV53989788; called by muse, mutect2, varscan2
- PKD1 | c.4545C>T p.H1515= | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as rs755083696, COSV51920905; called by muse, mutect2, varscan2
- RGS10 | c.177T>C p.N59= (on ENST00000369101; = p.N53= on NM_002925.3) | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV64862391; called by muse, mutect2, varscan2
- SLC6A17 | c.978C>T p.D326= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV58994922; called by muse, mutect2
- N4BP2L2 | chr13:32442429 A>T | 3'Flank (SNP) | VAF 3/22 reads (14%) | catalogued as COSV62634066; called by muse, mutect2
